Somatic mutation profile of tumor specimen TCGA-RW-A688-01A (aliquot TCGA-RW-A688-01A-11D-A35D-08) from TCGA case TCGA-RW-A688, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 69.0 years (25,216 days).
Specimen TCGA-RW-A688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6db4da5-b261-4dd5-af55-95d8ea429efe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A688-10B (Blood Derived Normal), aliquot TCGA-RW-A688-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9491b516-33bd-4c17-b451-c3e5dd7c8486

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC7 | c.634del p.L212Ffs*3 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV101484815; called by mutect2, pindel, varscan2
- MGST1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs139915404; called by muse, mutect2, varscan2
- UNC79 | c.6142A>G p.I2048V (on ENST00000393151 / NM_001346218.2; = p.I1871V on NM_020818.5) | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs192563227; called by muse, mutect2, varscan2
- DENND4A | c.4631T>G p.V1544G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EHF | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERCC6L | c.3436C>A p.P1146T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- MED12 | c.3984T>A p.H1328Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- NF1 | c.567del p.K189Nfs*2 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | called by mutect2, pindel, varscan2
- PHIP | c.3308A>G p.Y1103C | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAD54L2 | c.4194G>C p.A1398= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV56580343; called by muse, mutect2, varscan2
- RBM42 | c.651G>T p.P217= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs750153748, COSV52896987, COSV52899530; called by muse, mutect2, varscan2
